Somatic mutation profile of tumor specimen ALCH-B2YF-TTP1-A (aliquot ALCH-B2YF-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B2YF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.1 years (26,346 days).
Specimen ALCH-B2YF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdaf3983-dcf3-4bc7-afea-fb330a54b48a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2YF-NB1-A (Blood Derived Normal), aliquot ALCH-B2YF-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5af4941b-9aeb-435a-bc77-04c08a8d4352

The open-access MAF lists 263 somatic variants for this specimen: 181 protein-altering or splice-affecting, 50 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 50, Nonsense Mutation 22, Intron 15, 3'UTR 8, Splice Site 5, RNA 5, Splice Region 4, 5'UTR 3, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS20 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 45/675 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143824237; called by muse, mutect2
- ADAT3 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as rs1425999578; called by muse, mutect2, varscan2
- ADGRE4P | n.2431G>A | Splice Region (SNP) | VAF 34/317 reads (11%) | catalogued as rs761125784; called by muse, mutect2, varscan2
- ANKRD26 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 42/802 reads (5%) | catalogued as COSV65776569; called by muse, mutect2
- BCL2 | c.584G>T p.W195L | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61390692; called by muse, mutect2
- C10orf71 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 25/256 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100110344; called by muse, mutect2
- C10orf88 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 32/295 reads (11%) | catalogued as COSV64404303; called by muse, mutect2, varscan2
- CACNA1E | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62409958; called by muse, mutect2
- CACNA1H | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as COSV61992265; called by muse, mutect2
- CEP44 | c.961C>T p.H321Y | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as rs1383912195, COSV56658315; called by muse, mutect2
- CHURC1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as rs767232190; called by muse, mutect2, varscan2
- CLNK | c.682C>A p.H228N | Missense Mutation (SNP) | VAF 34/516 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs746693451, COSV99905242; called by muse, mutect2
- CLRN1 | c.668C>T p.T223I | Missense Mutation (SNP) | VAF 20/574 reads (3%) | SIFT tolerated (0.32); PolyPhen benign (0.138); catalogued as rs1269481048; called by muse, mutect2
- CPA3 | c.440C>A p.S147Y | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV99936570; called by muse, mutect2
- CSMD1 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 36/527 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); catalogued as rs371015364; called by muse, mutect2
- DKK4 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 37/375 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55183695; called by muse, mutect2
- DPP6 | c.1287G>C p.W429C (on ENST00000377770 / NM_001364500.2; = p.W367C on NM_001936.5) | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59626157; called by muse, mutect2
- EFR3B | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 38/380 reads (10%) | catalogued as rs773895355, COSV53122703; called by muse, mutect2
- EPHA3 | c.977C>A p.P326Q | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60726330; called by muse, mutect2
- EPHA7 | c.1502C>A p.S501Y | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV65189156; called by muse, mutect2
- EPS15 | c.2497A>G p.T833A | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.99); PolyPhen benign (0.049); catalogued as rs1239314829, COSV100869590; called by muse, mutect2
- ERG | c.425G>A p.S142N | Missense Mutation (SNP) | VAF 22/355 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as rs968569145; called by muse, mutect2
- FRAS1 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as rs199588297; called by muse, mutect2, varscan2
- FSTL5 | c.1568G>C p.R523T | Missense Mutation (SNP) | VAF 18/593 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60210002; called by muse, mutect2
- GC | c.832-1G>T p.X278_splice | Splice Site (SNP) | VAF 19/247 reads (8%) | catalogued as COSV56740652; called by muse, mutect2
- GFRA2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417715794, COSV60779989; called by muse, mutect2
- GPR142 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs374841372, COSV59518684; called by muse, varscan2
- GYPC | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 18/520 reads (3%) | catalogued as COSV52145937; called by muse, mutect2
- HOXB13 | c.698G>C p.R233P | Missense Mutation (SNP) | VAF 49/588 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51705295; called by muse, mutect2
- IGHV6-1 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs72715485; called by muse, mutect2, varscan2
- JPH3 | c.746G>T p.G249V | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs764074006, COSV52474876; called by muse, mutect2
- LRFN5 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 32/610 reads (5%) | catalogued as COSV53276042; called by muse, mutect2
- MUC19 | c.293G>T p.G98V | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.608); catalogued as COSV70100582; called by muse, mutect2
- NHLH2 | c.197A>T p.E66V | Missense Mutation (SNP) | VAF 15/234 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs776027891; called by muse, mutect2
- NLRP7 | c.548G>C p.G183A | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60183003; called by muse, mutect2
- OR52N5 | c.313G>T p.A105S | Missense Mutation (SNP) | VAF 32/315 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV99061101; called by muse, mutect2
- OTOF | c.4331C>A p.T1444N (on ENST00000272371 / NM_194248.3; = p.T677N on NM_004802.4) | Missense Mutation (SNP) | VAF 39/585 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.215); catalogued as rs1194946286; called by muse, mutect2
- PCDHB1 | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 27/452 reads (6%) | catalogued as COSV60629676; called by muse, mutect2
- PCDHGA9 | c.282G>T p.E94D | Missense Mutation (SNP) | VAF 19/440 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.33); catalogued as COSV53913328; called by muse, mutect2
- PCLO | c.11818G>T p.V3940F | Missense Mutation (SNP) | VAF 48/532 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs763593233; called by muse, mutect2
- PCSK1 | c.675C>A p.C225* | Nonsense Mutation (SNP) | VAF 64/987 reads (6%) | catalogued as COSV60735176; called by muse, mutect2
- PDGFRA | c.1560C>T p.T520= | Splice Region (SNP) | VAF 44/648 reads (7%) | catalogued as COSV99955883; called by muse, mutect2
- PIK3C2G | c.940C>A p.L314I | Missense Mutation (SNP) | VAF 21/548 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV56805167; called by muse, mutect2
- PRDM2 | c.2584G>T p.G862C | Missense Mutation (SNP) | VAF 26/458 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.846); catalogued as rs1408891862; called by muse, mutect2
- PREX2 | c.3946G>T p.V1316F | Missense Mutation (SNP) | VAF 44/346 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs751412933; called by muse, mutect2, varscan2
- RAB3GAP2 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 35/509 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs747553998; called by muse, mutect2
- RNASEH2A | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 45/467 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs771858022, COSV99677205; called by muse, mutect2, varscan2
- ROCK2 | c.3305G>T p.R1102L | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs766071383, COSV59953089; called by muse, mutect2
- RPGRIP1 | c.337C>G p.L113V | Missense Mutation (SNP) | VAF 30/422 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429217156; called by muse, mutect2
- SCART1 | c.2389G>T p.G797W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741562; called by muse, mutect2, varscan2
- SCN8A | c.2509G>T p.V837L | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.551); catalogued as COSV61987279; called by muse, mutect2
- SLC18A1 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 25/435 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1433856499, COSV52351749; called by muse, mutect2
- SNAI1 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753536560, COSV54863578; called by muse, mutect2
- THEMIS | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64069021; called by muse, mutect2
- TLR1 | c.1741C>G p.L581V | Missense Mutation (SNP) | VAF 46/601 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV58305428; called by muse, mutect2
- TRAK2 | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs199509240; called by muse, mutect2
- TRANK1 | c.7429G>T p.D2477Y | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100081392; called by muse, mutect2
- TTC21B | c.3736G>A p.A1246T | Missense Mutation (SNP) | VAF 40/867 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs372149260; called by muse, mutect2
- USF3 | c.1344G>T p.Q448H | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57072672; called by muse, mutect2, varscan2
- XIRP2 | c.8650G>A p.V2884I (on ENST00000628543; = p.V3059I on NM_152381.6) | Missense Mutation (SNP) | VAF 30/556 reads (5%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1004137979, COSV54680952, COSV54708255; called by muse, mutect2
- YIPF7 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1325094238; called by muse, mutect2
- ZNF711 | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 22/399 reads (6%) | catalogued as COSV52154579, COSV52154777; called by muse, mutect2
- ZNF800 | c.199A>G p.T67A | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as rs112060462; called by muse, mutect2
- ACTL9 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.251); called by muse, mutect2
- ACVR2B | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 56/575 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANK2 | c.4078C>A p.Q1360K | Missense Mutation (SNP) | VAF 52/690 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGAP31 | c.760C>T p.Q254* | Nonsense Mutation (SNP) | VAF 14/304 reads (5%) | called by muse, mutect2
- ARHGAP5 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 15/300 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- ASB7 | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 20/528 reads (4%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.961); called by muse, mutect2
- ASPM | c.7141T>A p.Y2381N | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2
- ATP10B | c.2523G>T p.K841N | Missense Mutation (SNP) | VAF 46/439 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTBD8 | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 31/295 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- C4orf54 | c.664C>G p.Q222E | Missense Mutation (SNP) | VAF 17/358 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.398); called by muse, mutect2
- CCNT2 | c.499A>T p.K167* | Nonsense Mutation (SNP) | VAF 42/570 reads (7%) | called by muse, mutect2
- CDCA7L | c.428G>C p.R143P | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CES1 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 41/414 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.152); called by muse, mutect2
- CHD6 | c.3781G>T p.D1261Y | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CLCN7 | c.917G>C p.G306A | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- COL5A3 | c.4812G>T p.K1604N | Missense Mutation (SNP) | VAF 9/164 reads (5%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.934); called by muse, mutect2
- CRACD | c.748G>C p.E250Q | Missense Mutation (SNP) | VAF 14/480 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2
- DCDC2C | c.586G>C p.D196H | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2
- DGKB | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.013); called by muse, mutect2
- DYSF | c.2520G>T p.M840I | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- DYSF | c.4334-1G>T p.X1445_splice | Splice Site (SNP) | VAF 32/471 reads (7%) | called by muse, mutect2
- EGFLAM | c.2864T>A p.M955K (on ENST00000354891 / NM_001205301.2; = p.M947K on NM_152403.4) | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- EIF3B | c.1744G>T p.G582* | Nonsense Mutation (SNP) | VAF 31/303 reads (10%) | called by muse, mutect2, varscan2
- EVC2 | c.3185G>T p.G1062V | Missense Mutation (SNP) | VAF 24/668 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2
- EXO1 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM160B1 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 49/608 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.671); called by muse, mutect2
- FAT3 | c.7395C>A p.Y2465* | Nonsense Mutation (SNP) | VAF 21/267 reads (8%) | called by muse, mutect2
- FAT4 | c.6910G>A p.E2304K | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.914); called by muse, mutect2
- FBLN1 | c.1991G>C p.R664P | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); called by muse, mutect2
- FBN2 | c.1251C>A p.C417* | Nonsense Mutation (SNP) | VAF 35/438 reads (8%) | called by muse, mutect2
- FBXO34 | c.1930G>C p.V644L | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2
- GABRB3 | c.505C>G p.P169A | Missense Mutation (SNP) | VAF 45/1030 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPAT3 | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 42/493 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- GPR135 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2
- HGF | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 40/662 reads (6%) | called by muse, mutect2
- HMCN1 | c.871G>T p.E291* | Nonsense Mutation (SNP) | VAF 83/987 reads (8%) | called by muse, mutect2
- HOXD11 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 22/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IL4R | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.127); called by muse, mutect2
- IQGAP1 | c.3182G>T p.G1061V | Missense Mutation (SNP) | VAF 53/643 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KCNJ4 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- KCTD3 | c.1311C>A p.V437= | Splice Region (SNP) | VAF 10/247 reads (4%) | called by muse, mutect2
- LRFN5 | c.274C>G p.P92A | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.823); called by muse, mutect2
- MAGI2 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAP4K5 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 52/336 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MARS2 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2
- MEI1 | c.2969T>C p.L990P | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MFSD6 | c.1609C>G p.L537V | Missense Mutation (SNP) | VAF 36/609 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MKRN3 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- MMS22L | c.269G>C p.R90T | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- MTRES1 | c.496G>C p.G166R | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2
- MUC16 | c.20295C>A p.H6765Q | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MYO3A | c.328G>C p.D110H | Missense Mutation (SNP) | VAF 46/836 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MYT1L | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 52/796 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.6); called by muse, mutect2
- NAA11 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 43/501 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- NALCN | c.1745A>G p.Y582C | Missense Mutation (SNP) | VAF 37/398 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NDUFAF2 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 45/582 reads (8%) | called by muse, mutect2
- NEK5 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 52/663 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- NLRP5 | c.1432T>A p.C478S | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.677); called by muse, mutect2
- NRXN2 | c.1823G>T p.S608I | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.03); called by muse, mutect2
- OR4K2 | c.703A>T p.K235* | Nonsense Mutation (SNP) | VAF 48/1114 reads (4%) | called by muse, mutect2
- OR4M1 | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 32/964 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.136); called by muse, mutect2
- OR51M1 | c.863T>A p.M288K | Missense Mutation (SNP) | VAF 26/554 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- OR51M1 | c.864G>T p.M288I | Missense Mutation (SNP) | VAF 25/551 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.06); called by muse, mutect2
- OR6F1 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.054); called by muse, mutect2
- OTOP3 | c.892G>T p.G298C | Missense Mutation (SNP) | VAF 46/280 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PABPC3 | c.576T>A p.N192K | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDHB11 | c.445G>T p.G149C | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGA8 | c.385A>G p.N129D | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- PCDHGB3 | c.1999A>G p.S667G | Missense Mutation (SNP) | VAF 18/496 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- PGAM2 | c.110A>C p.E37A | Missense Mutation (SNP) | VAF 48/788 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIK3R2 | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.044); called by muse, mutect2
- PIP4K2A | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLA2G6 | c.609+1G>C p.X203_splice | Splice Site (SNP) | VAF 50/1158 reads (4%) | called by muse, mutect2
- PLEK | c.846G>T p.G282= | Splice Region (SNP) | VAF 38/458 reads (8%) | called by muse, mutect2
- POU4F2 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 31/383 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); called by muse, mutect2
- PPIL3 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 27/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP1R16A | c.227T>C p.L76P | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP2R1A | c.334T>A p.L112I | Missense Mutation (SNP) | VAF 41/287 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PPP2R3A | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.054); called by muse, mutect2
- PRUNE2 | c.7954G>T p.G2652W | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); called by muse, mutect2
- PTGFRN | c.343G>T p.G115C | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAB6C | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 38/653 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2
- RBM15 | c.2800G>T p.D934Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- REG1A | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2
- RNF4 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 21/474 reads (4%) | SIFT tolerated (0.92); PolyPhen benign (0.001); called by muse, mutect2
- RUBCNL | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RYR3 | c.2197C>T p.Q733* | Nonsense Mutation (SNP) | VAF 16/384 reads (4%) | called by muse, mutect2
- SEMA3C | c.2169G>T p.Q723H | Missense Mutation (SNP) | VAF 75/755 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH2D7 | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 12/167 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2
- SHCBP1 | c.1159G>T p.G387C | Missense Mutation (SNP) | VAF 17/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC7A11 | c.746+1G>T p.X249_splice | Splice Site (SNP) | VAF 16/235 reads (7%) | called by muse, mutect2
- SP4 | c.1469T>A p.L490* | Nonsense Mutation (SNP) | VAF 42/538 reads (8%) | called by muse, mutect2
- SPEF2 | c.3286T>A p.W1096R | Missense Mutation (SNP) | VAF 34/520 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.65); called by muse, mutect2
- SPTA1 | c.4033T>A p.F1345I | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2
- SRCAP | c.5230C>T p.Q1744* | Nonsense Mutation (SNP) | VAF 14/403 reads (3%) | called by muse, mutect2
- SUPT20HL1 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 38/408 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.001); called by muse, mutect2
- TLE4 | c.608A>G p.K203R | Missense Mutation (SNP) | VAF 42/636 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- TNN | c.2266G>T p.G756W | Missense Mutation (SNP) | VAF 42/591 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- TONSL | c.1481-2A>T p.X494_splice | Splice Site (SNP) | VAF 38/217 reads (18%) | called by muse, mutect2, varscan2
- TRAM1L1 | c.894dup p.A299Cfs*30 | Frame Shift Ins (INS) | VAF 24/270 reads (9%) | called by mutect2, pindel
- TSPAN31 | c.72C>A p.S24R | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2
- TTN | c.59134G>T p.D19712Y (on ENST00000591111; = p.D12288Y on NM_003319.4) | Missense Mutation (SNP) | VAF 32/492 reads (7%) | PolyPhen possibly damaging (0.858); called by muse, mutect2
- TUBB4A | c.203T>A p.L68Q | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UNC79 | c.878A>G p.Y293C (on ENST00000393151 / NM_001346218.2; = p.Y116C on NM_020818.5) | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); called by muse, mutect2
- USP35 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 8/116 reads (7%) | called by muse, mutect2
- VANGL1 | c.704A>C p.Y235S | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZC3H7B | c.2640G>T p.W880C | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZDHHC17 | c.598A>G p.R200G | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- ZFYVE1 | c.1512G>T p.W504C | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZFYVE28 | c.1409G>T p.G470V | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2
- ZNF17 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 40/434 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.141); called by muse, mutect2
- ZNF236 | c.4220A>C p.Q1407P | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- ZNF502 | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 15/178 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.081); called by muse, mutect2
- ZNF57 | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 9/115 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF585B | c.1321G>C p.G441R | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); called by muse, mutect2
- ZNF676 | c.1634C>T p.A545V (on ENST00000650058; = p.A513V on NM_001001411.3) | Missense Mutation (SNP) | VAF 40/916 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); called by muse, mutect2
- ZNF804B | c.2785T>A p.L929I | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF841 | c.494T>G p.M165R (on ENST00000426391 / NM_001369830.1; = p.M281R on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ACTR1B | c.372G>T p.A124= | Silent (SNP) | VAF 32/428 reads (7%) | catalogued as COSV56704539; called by muse, mutect2
- ADAM30 | c.669T>A p.L223= | Silent (SNP) | VAF 22/366 reads (6%) | called by muse, mutect2
- AKAP9 | c.8652C>T p.A2884= (on ENST00000359028; = p.A2860= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/112 reads (9%) | catalogued as rs754777973, COSV100663273; called by muse, mutect2
- ARHGAP9 | c.1594C>A p.R532= (on ENST00000393797 / NM_001319850.2; = p.R513= on NM_032496.4) | Silent (SNP) | VAF 16/169 reads (9%) | called by muse, mutect2
- CACNA1H | c.3090C>T p.D1030= | Silent (SNP) | VAF 17/221 reads (8%) | catalogued as rs564292386, COSV61982710; called by muse, mutect2
- CDHR2 | c.3621C>A p.A1207= | Silent (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
- CENPF | c.8394G>A p.L2798= | Silent (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- COL11A1 | c.4179C>A p.G1393= | Silent (SNP) | VAF 47/768 reads (6%) | called by muse, mutect2
- CORO6 | c.165C>T p.G55= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as rs759211260, COSV52169737; called by muse, mutect2
- COX6A2 | c.165G>C p.P55= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV54932028; called by muse, mutect2
- DISP3 | c.2562T>A p.P854= | Silent (SNP) | VAF 17/140 reads (12%) | called by muse, varscan2
- DNAH3 | c.2742C>T p.I914= | Silent (SNP) | VAF 55/542 reads (10%) | called by muse, mutect2
- GDF10 | c.543G>T p.T181= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs1555207451; called by muse, mutect2
- GRID2 | c.315C>A p.L105= | Silent (SNP) | VAF 20/270 reads (7%) | catalogued as COSV99938883; called by muse, mutect2
- HMCN2 | c.162G>A p.Q54= | Silent (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- IL4I1 | c.57G>T p.V19= | Silent (SNP) | VAF 36/236 reads (15%) | called by muse, mutect2, varscan2
- KCNA5 | c.1197C>A p.L399= | Silent (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- KCNA5 | c.1198C>A p.R400= | Silent (SNP) | VAF 21/171 reads (12%) | catalogued as rs773432359, COSV52905456; called by muse, mutect2, varscan2
- KIFC2 | c.1107G>T p.R369= | Silent (SNP) | VAF 35/195 reads (18%) | called by muse, mutect2, varscan2
- LCT | c.2262G>T p.G754= | Silent (SNP) | VAF 39/632 reads (6%) | called by muse, mutect2
- LLGL1 | c.2853T>C p.I951= | Silent (SNP) | VAF 28/333 reads (8%) | catalogued as rs1334533368; called by muse, mutect2
- MAGEA11 | c.1236T>G p.T412= | Silent (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- MDGA2 | c.48C>A p.R16= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2, varscan2
- MEI1 | c.120C>A p.T40= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- MROH2B | c.2724C>A p.A908= | Silent (SNP) | VAF 29/620 reads (5%) | catalogued as rs779389070; called by muse, mutect2
- NMUR2 | c.372C>A p.A124= | Silent (SNP) | VAF 25/276 reads (9%) | called by muse, mutect2
- NOTCH1 | c.5550C>T p.A1850= | Silent (SNP) | VAF 21/382 reads (5%) | catalogued as rs374451515; ClinVar: likely benign; called by muse, mutect2
- NTRK3 | c.987C>G p.P329= | Silent (SNP) | VAF 17/238 reads (7%) | catalogued as COSV58142537; called by muse, mutect2
- OR1L3 | c.915C>T p.N305= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs150477897; called by muse, mutect2
- OR51A4 | c.243C>T p.P81= | Silent (SNP) | VAF 58/879 reads (7%) | catalogued as rs1230711486; called by muse, mutect2
- OSBPL1A | c.1341G>A p.L447= | Silent (SNP) | VAF 48/610 reads (8%) | catalogued as rs1338552787; called by muse, mutect2
- PAPPA2 | c.1140G>T p.V380= | Silent (SNP) | VAF 18/234 reads (8%) | called by muse, mutect2
- PCDHGC5 | c.1506A>T p.P502= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV99338771; called by muse, mutect2
- PCYT2 | c.297A>G p.L99= | Silent (SNP) | VAF 31/249 reads (12%) | called by muse, mutect2, varscan2
- PRKD1 | c.393G>T p.V131= | Silent (SNP) | VAF 18/312 reads (6%) | called by muse, mutect2
- PRR33 | c.429T>A p.A143= | Silent (SNP) | VAF 13/143 reads (9%) | called by muse, mutect2, varscan2
- RETREG1 | c.256C>T p.L86= | Silent (SNP) | VAF 34/406 reads (8%) | catalogued as rs751029157; called by muse, mutect2
- RP1L1 | c.963G>C p.L321= | Silent (SNP) | VAF 28/400 reads (7%) | called by muse, mutect2
- SLC6A5 | c.96C>A p.P32= | Silent (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- SLCO2A1 | c.1776G>A p.G592= | Silent (SNP) | VAF 7/68 reads (10%) | called by mutect2, varscan2
- SORCS1 | c.3489G>T p.G1163= | Silent (SNP) | VAF 38/301 reads (13%) | catalogued as COSV53883674; called by muse, mutect2, varscan2
- SPAG1 | c.1416C>T p.I472= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as rs1183762592; called by muse, varscan2
- TLN1 | c.5163G>T p.R1721= | Silent (SNP) | VAF 23/299 reads (8%) | called by muse, mutect2
- TMEM130 | c.798G>A p.L266= | Silent (SNP) | VAF 9/84 reads (11%) | called by muse, mutect2, varscan2
- TSPAN7 | c.291G>C p.L97= | Silent (SNP) | VAF 46/526 reads (9%) | called by muse, mutect2
- UGT2B10 | c.1437C>A p.A479= | Silent (SNP) | VAF 72/792 reads (9%) | called by muse, mutect2
- WDR25 | c.1200G>T p.R400= | Silent (SNP) | VAF 17/269 reads (6%) | called by muse, mutect2
- WT1 | c.687G>T p.G229= | Silent (SNP) | VAF 40/461 reads (9%) | called by muse, mutect2
- ZNF358 | c.1272A>C p.L424= | Silent (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- ZNF626 | c.1533G>T p.V511= | Silent (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- AC018638.4 | n.839G>T | RNA (SNP) | VAF 53/814 reads (7%) | called by muse, mutect2
- AC243919.1 | n.416-21T>A | Intron (SNP) | VAF 24/726 reads (3%) | called by muse, mutect2
- AFF2 | c.-24G>A | 5'UTR (SNP) | VAF 18/84 reads (21%) | catalogued as rs375802594; called by mutect2, varscan2
- BCL9L | c.*592G>T | 3'UTR (SNP) | VAF 48/450 reads (11%) | called by muse, mutect2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs73150876; called by muse, varscan2
- CSMD3 | c.178+59875C>A | Intron (SNP) | VAF 117/947 reads (12%) | catalogued as COSV52207128; called by muse, mutect2, varscan2
- CXCL14 | c.-21C>T | 5'UTR (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- FAM90A27P | n.1157G>T | RNA (SNP) | VAF 12/167 reads (7%) | called by muse, mutect2
- FSD1L | c.1026-3924G>T | Intron (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- GRB10 | c.*2C>A | 3'UTR (SNP) | VAF 24/412 reads (6%) | called by muse, mutect2
- IFNGR1 | c.200+46A>C | Intron (SNP) | VAF 31/248 reads (13%) | called by muse, mutect2, varscan2
- IL6 | c.20-48C>A | Intron (SNP) | VAF 22/333 reads (7%) | catalogued as rs779605333; called by muse, mutect2
- LIPN | c.535+28G>T | Intron (SNP) | VAF 61/664 reads (9%) | called by muse, mutect2
- MCF2 | c.*102G>T | 3'UTR (SNP) | VAF 22/221 reads (10%) | catalogued as COSV100644746; called by muse, mutect2, varscan2
- MGAM | c.4619-227G>C | Intron (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- MORN1 | c.745+642G>T | Intron (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2
- MSR1 | c.1033+2578C>A | Intron (SNP) | VAF 43/442 reads (10%) | called by muse, mutect2
- MUC12 | c.*23C>T | 3'UTR (SNP) | VAF 5/71 reads (7%) | catalogued as COSV59332039; called by muse, mutect2
- NFASC | c.*19A>T | 3'UTR (SNP) | VAF 34/534 reads (6%) | called by muse, mutect2
- NOC2LP2 | n.946C>T | RNA (SNP) | VAF 38/558 reads (7%) | catalogued as rs545545470; called by muse, mutect2
- NOC2LP2 | n.651C>A | RNA (SNP) | VAF 32/466 reads (7%) | called by muse, mutect2
- NSMF | c.*4G>T | 3'UTR (SNP) | VAF 30/252 reads (12%) | called by mutect2, varscan2
- OMD | c.*1C>A | 3'UTR (SNP) | VAF 9/97 reads (9%) | catalogued as rs1286392235; called by muse, mutect2
- PCDHGA3 | c.2425-68080G>C | Intron (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- RIMS2 | c.177-44409A>T | Intron (SNP) | VAF 79/737 reads (11%) | called by muse, mutect2, varscan2
- RNF170 | c.*2182G>C | 3'UTR (SNP) | VAF 58/1022 reads (6%) | catalogued as COSV53566110; called by muse, mutect2
- SDHAP2 | n.501A>T | RNA (SNP) | VAF 66/1160 reads (6%) | called by muse, mutect2
- SRP19 | c.-9C>T | 5'UTR (SNP) | VAF 22/298 reads (7%) | catalogued as rs1030797350; called by muse, mutect2
- TMEM18 | c.57+699G>T | Intron (SNP) | VAF 14/213 reads (7%) | catalogued as rs1279143056; called by muse, mutect2
- TRAPPC9 | chr8:140458458 G>T | 5'Flank (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2
- VPS37A | c.125+989G>T | Intron (SNP) | VAF 40/374 reads (11%) | catalogued as rs779758388; called by muse, varscan2
- ZMIZ1 | c.541-177G>T | Intron (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2, varscan2
